Gene-level copy-number profile of tumor specimen C3L-04392-03 from CPTAC case C3L-04392, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 80.8 years (29,515 days).
Specimen C3L-04392-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9948e073-4da5-4bc2-8d7c-80b69f4a2a17.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04392-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/d5399698-137f-458c-8a40-18875ab22b9d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 205; copy number 1: 49; copy number 2: 4,742; copy number 3: 505; copy number 4: 40,569; copy number 5: 3,928; copy number 6: 5,567; copy number 7: 481; copy number 8: 464; copy number 9: 1,885; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 205 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:77,963,940–78,544,269, 7 genes: HMGB1P44, HNRNPA1P56, AC114801.1, AC114801.3, FRAS1, SERBP1P5, MICOS10P4.
- chr9:21,077,104–22,214,672, 53 genes: IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:52,972,612–58,370,751, 30 genes: LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1, PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1, AC051618.1, AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1, ZWINT, AC025039.1, MIR3924, AL731534.1, AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10, CISD1, AC016396.1, AC016396.2, UBE2D1.
- chr10:87,945,502–87,994,695, 2 genes (within-gene range 0–4): RPL11P3, AC063965.1.
- chr13:87,219,004–96,839,562, 100 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:19,131,842–19,384,587, 13 genes (within-gene range 0–3): AL589182.2, OR11H13P, AL589743.2, AL589743.4, CDRT15P13, NBEAP6, AL589743.1, TOMM40P1, DUXAP10, BMS1P17, AL929602.1, LINC01297, GRAMD4P3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,886 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,414,855–7,463,674, 4 genes, copy number 9: DEFB4B, HSPD1P3, DEFB103B, SPAG11B.
- chr8:7,926,337–7,952,413, 1 gene, copy number 9 (within-gene range 5–9): ZNF705B.
- chr8:7,955,014–12,115,516, 128 genes, copy number 9 (broad region; genes not listed).
- chr8:12,178,697–15,238,431, 59 genes, copy number 9: ALG1L11P, FAM86B1, AC145124.1, ENPP7P12, DEFB131D, DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1, RPS3AP34, AC068587.2, RPS3AP35, AC068587.3, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1, MIR383, AC084838.1.
- chr8:16,598,758–16,915,044, 1 gene, copy number 9 (within-gene range 2–9): AC011586.2.
- chr8:16,863,196–116,944,487, 1,553 genes, copy number 9–13 (broad region; genes not listed).
- chr8:142,834,247–145,066,685, 139 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr10:38,601,418–38,605,609, 1 gene, copy number 9: ABCD1P2.

Autosomal genes at a single copy (total copy number 1): 49. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
